Somatic mutation profile of tumor specimen MP2PRT-PAUKFW-TBP1-A (aliquot MP2PRT-PAUKFW-TBP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAUKFW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,571 days).
Specimen MP2PRT-PAUKFW-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07558543-a666-4ac3-9bc7-7bcad01bbce8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKFW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKFW-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0cb0e0e-7bb3-44fa-811e-e56e947be2ce

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEBP1 | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 19/368 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GALNT6 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 22/589 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2
- MAPRE1 | c.20C>G p.S7* | Nonsense Mutation (SNP) | VAF 13/350 reads (4%) | called by muse, mutect2
- WDR62 | c.308A>C p.Q103P | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2
- ZSWIM6 | c.3162G>C p.M1054I | Missense Mutation (SNP) | VAF 15/526 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.281); called by muse, mutect2
- FAT1 | c.3585C>G p.L1195= | Silent (SNP) | VAF 18/395 reads (5%) | catalogued as COSV71674643; called by muse, mutect2
- RGL1 | c.-366G>T | 5'UTR (SNP) | VAF 20/479 reads (4%) | called by muse, mutect2
